Surgical pathology report (de-identified scan), TCGA case TCGA-VW-A7QS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Northwestern University, specimen TCGA-VW-A7QS-01A (Primary Tumor).

[page 1 of 2]
Surgery Date:

Diagnosis

A & B. RIGHT FROTALESION, RESECTION:

--ANAPLASTIC OLIGODENDROGLIOMA, WHO GRADE III,
WITH COMBINED EQUIVALENT 1p19q DELETION (SEE COMMENT)

NOTE: Tumor cells are predominantly small, with intermingled mini-gemistocytic type cells, with round to oval bland nuclei and perinuclear halos. Although there is no microvascular proliferation or necrosis, some areas show increased mitotic activity up to 6-7 mitoses per high-power field, consistent with anaplastic oligodendroglioma. Tumor cells are strongly positive for IDH1 and only rare nuclei are positive for p53 (block B4). Overall Ki-67 labeling index is less than 5%. However, there are a few nodules with proliferation index exceeding 30%.

This test was developed and its performance characteristics were determined by the

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

The positive control demonstrate appropriate positive staining. The known tissue negative controls were negative. The non-immune serum control was non-reactive.

Fluorescence in-situ hybridization (FISH) testing is performed for the following markers on block B4 and the results are as follows:

Ratio 1p to 1q: 0.59

Percent of cells with 1q to 1p ratio ≥ 2 : 73%

Ratio 19q to 19p: 0.57

Percent of cells with 19p to 19q ratio ≥ 2 : 73%

Reference range:

No deletion: Ratio of test probe to reference probe > 0.8

Deletion: Ratio of test probe to reference probe ≤ 0.8 and $\geq 15\%$ of cells showing reference:target ratio ≥ 2

Polysomy: $\geq 30\%$ of cells have 3 or more signals for 1q or 19p

Relative deletion: Ratio of test to reference probe signals ≤ 0.5 , where reference probe signals > 2

ICD 03
Oligodendroglioma, grade III
945113
Site CCE
Brain, supratentorial NOS
C71.0
path
Brain, frontal lobe
C71.1
JW 4/4/14

Comment: Chromosomal 1p, 19q deletion is combined equivalent.

Testing utilizes probes and reagents determined by the

This test was developed and its performance characteristics determined by the, certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing. This test has not been cleared or approved by the U.S. Food and Drug Administration; however, the FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes and should not be regarded as investigational or for research.

(Electronically signed by)

Date Finald:

I, the Attending Pathologist attest by my signature, that this case has been personally reviewed and examined, microscopically and/or grossly and the diagnosis(es) has been made or confirmed by me.

[page 2 of 2]
Surgery Date:

Clinical Information

The patient is a -year-old female with clinical diagnosis of right frontal tumor, undergoing craniotomy for tumor.

Gross Description

A. The specimen is received fresh intraoperatively for consultation from ; labeled with the patient's name and designated on the requisition as "brain tumor." The specimen consists of a single fragment of red-tan, soft tissue measuring 1.8 x 1.5 x 0.8 cm. Smear and frozen preparations are made and the intraoperative diagnosis by is **"HIGH-GRADE GLIOMA, FAVOR OLIGODENDROGLIOMA."** The intraoperative consultation diagnosis is communicated to the operating room at . The frozen tissue is submitted in one cassette and the remaining tissue is submitted in one cassette.

B. Received fresh, labeled with the patient's name and designated on the requisition as "brain tumor." The specimen consists of multiple fragments of red-tan, soft tissue measuring 5 x 5 x 2 cm in aggregate. On cut section, the specimen has some bloody and yellow foci. The specimen is serially sectioned and submitted entirely in 20 cassettes.

Frozen Section Diagnosis

A. **"HIGH-GRADE GLIOMA, FAVOR OLIGODENDROGLIOMA."**

Source: NCI Genomic Data Commons file 093f3e4b-a15d-4150-bbea-21e742e9ab77 (TCGA-VW-A7QS.47DD727D-85CE-4CBC-8FE6-7003BF110D4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).